Gene-level copy-number profile of tumor specimen ALCH-B1ZS-TTP1-A from ALCHEMIST case ALCH-B1ZS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 79.6 years (29,079 days).
Specimen ALCH-B1ZS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b5a8b96a-f1ea-42ea-978f-b52a30960124.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1ZS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/99410263-aef8-4e72-a9bd-535790517fa0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 122; copy number 1: 1,322; copy number 2: 8,999; copy number 3: 16,518; copy number 4: 20,234; copy number 5: 9,105; copy number 6: 1,044; copy number 7: 310; copy number 8: 173; copy number 9: 6; copy number 10: 9; copy number 13: 107; copy number 14: 46; copy number 15: 1; copy number 20: 33; copy number 21: 251; copy number 24: 108; copy number 29: 8.

Homozygous deletions (total copy number 0; autosomes only): 122 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr9:20,331,446–26,118,408, 86 genes (broad region; genes not listed).
- chr9:29,254,075–31,645,160, 19 genes: AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr13:37,534,940–37,551,536, 1 gene: LINC00547.
- chr13:57,140,918–57,204,799, 7 genes: PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 569 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,929,720–120,467,739, 51 genes, copy number 9–21: WDR3, SPAG17, RNA5SP56, PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2.
- chr3:166,160,021–166,294,353, 6 genes, copy number 10: MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1.
- chr3:167,065,831–186,362,234, 330 genes, copy number 20–24 (broad region; genes not listed).
- chr3:195,068,284–195,443,044, 10 genes, copy number 13 (within-gene range 5–13): XXYLT1, XXYLT1-AS1, MIR3137, RN7SL36P, XXYLT1-AS2, RNU6-25P, AC090018.2, ACAP2, ACAP2-IT1, AC090018.1.
- chr9:32,293,558–34,520,988, 89 genes, copy number 13 (broad region; genes not listed).
- chr13:18,467,172–18,492,419, 2 genes, copy number 9: ZNF962P, BNIP3P7.
- chr15:43,663,654–43,684,339, 1 gene, copy number 15 (within-gene range 6–15): AC011330.1.
- chr18:23,957,754–27,595,164, 69 genes, copy number 14–21 (broad region; genes not listed).
- chr21:12,999,676–13,489,176, 11 genes, copy number 10–29: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P.

Autosomal genes at a single copy (total copy number 1): 1,322. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
